TARGET case TARGET-20-PAVKJD — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0eb2426d-28f8-4f34-a891-d80b4f64b515

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.5 years (929 days); Year of diagnosis: 2013; Days to last follow up: 2,062 days (5.6 years); Sites of involvement: Central nervous system.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (2 entries)
- Days to follow up: 699 days (1.9 years); Days to first event: 699 days (1.9 years); First event: Relapse.
- Days to follow up: 2,062 days (5.6 years); Year of follow up: 2018.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Positive.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosome arm: q.
- Test: Positive; Chromosomal translocation: t(9;11)(p22;q23).
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- Day 0: Leukocytes 5.8 ×10³/µL; Blast Count 0%; Bone Marrow blast count 75%.
- Minimal Residual Disease (Flow Cytometry): Negative.

Biospecimens (3 samples)
- Sample TARGET-20-PAVKJD-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-20-PAVKJD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-20-PAVKJD-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AML1031_20230720.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2062
- WBC at Diagnosis: 5.8
- Bone marrow leukemic blast percentage (%): 75
- Peripheral blasts (%): 0
- CNS disease: Yes
- Chloroma: No
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): Yes
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: Yes
- Minus Y: No
- Minus X: No
- Cytogenetic Code Other: der(X)t(X;11)(q26;q23),del(2)(q35),del(11)(q13q24),add(18)(q23)
- Cytogenetic Complexity: >6
- Primary Cytogenetic Code: MLL
- ISCN: 47,X,der(X)t(X;11)(q26;q23),del(2)(q35),der(3)(3pter->3p22::3q21->3p22::3q21->3q25::?::11q13->11q23::3q26.1->3qter),der(9)t(9;11)(p22;q23),del(11)(q13q24),+19[16]/47,idem,add(18)(q23)[4]
- FLT3/ITD positive?: No
- NPM mutation: No
- CEBPA mutation: No
- MRD at end of course 1: No
- MRD % at end of course 1: 0
- MRD at end of course 2: No
- MRD % at end of course 2: 0
- CR status at end of course 1: CR
- CR status at end of course 2: CR
- Risk group: Standard Risk
- SCT in 1st CR: No
- Bone Marrow Site of Relapse/Induction Failure: Yes
- CNS Site of Relapse/Induction Failure: No
- Chloroma Site of Relapse/Induction Failure: No
- Cytogenetic Site of Relapse/Induction Failure: No
- Other Site of Relapse/Induction Failure: No
